Somatic mutation profile of tumor specimen TCGA-J9-A8CK-01A (aliquot TCGA-J9-A8CK-01A-11D-A34U-08) from TCGA case TCGA-J9-A8CK, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 66.5 years (24,285 days).
Specimen TCGA-J9-A8CK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 89a2070f-5e7c-4730-98e5-b59aa8af97a7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-J9-A8CK-10A (Blood Derived Normal), aliquot TCGA-J9-A8CK-10A-01D-A34X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f4c6c1cc-3587-4d99-9ad7-86efbf900fde

The open-access MAF lists 19 somatic variants for this specimen: 18 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Splice Region 1, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.836G>A p.G279E | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1064793881, COSV52677880, COSV52851240; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAM10 | c.1045C>T p.L349F | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.091); catalogued as COSV99546335; called by muse, mutect2, varscan2
- ANK3 | c.3380C>T p.T1127M (on ENST00000280772 / NM_001320874.2; = p.T261M on NM_001149.3) | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1248267868, COSV99781224; called by muse, mutect2, varscan2
- CADM3 | c.266C>T p.T89M (on ENST00000368125 / NM_001127173.3; = p.T123M on NM_021189.5) | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs748945624, COSV63684507; called by muse, mutect2, varscan2
- CHRNA1 | c.781G>A p.V261I (on ENST00000261007 / NM_001039523.3; = p.V236I on NM_000079.4) | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.035); catalogued as rs1332781017, COSV53684586; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL5A1 | c.1508G>A p.R503H | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.041); catalogued as rs146716315, COSV100879830; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CYP2C9 | c.902C>T p.T301M | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs757970831, COSV99582962; called by muse, mutect2, varscan2
- DZIP1L | c.1201A>T p.M401L | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV100551573; called by muse, mutect2, varscan2
- EIF4E3 | c.405G>A p.T135= (on ENST00000425534 / NM_001134651.2; = p.T29= on NM_173359.5) | Splice Region (SNP) | VAF 16/66 reads (24%) | catalogued as rs530682446, COSV99816570; called by muse, mutect2, varscan2
- EPB41L2 | c.2084G>A p.R695Q | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs753274531, COSV100441123; called by muse, mutect2, varscan2
- ETV6 | c.1159A>G p.T387A | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.05); catalogued as COSV99844747; called by muse, mutect2
- MUC16 | c.32189C>T p.S10730L | Missense Mutation (SNP) | VAF 64/235 reads (27%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.071); catalogued as COSV101200553; called by muse, mutect2, varscan2
- PACS2 | c.263T>C p.V88A | Missense Mutation (SNP) | VAF 25/129 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.278); catalogued as COSV100330885; called by muse, mutect2, varscan2
- PTCHD4 | c.1766G>A p.R589Q | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.52); PolyPhen benign (0.029); catalogued as rs534112009, COSV59785677, COSV59787501; called by muse, mutect2, varscan2
- RXYLT1 | c.215A>G p.D72G | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99707037; called by muse, mutect2, varscan2
- SUSD1 | c.1856A>G p.Y619C | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100813420; called by muse, mutect2, varscan2
- VSIG10 | c.209A>G p.N70S | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as COSV100821330; called by muse, mutect2, varscan2
- CREB3L2 | c.1259del p.T420Kfs*5 | Frame Shift Del (DEL) | VAF 15/85 reads (18%) | called by mutect2, pindel, varscan2
- MIR100 | n.15C>T | RNA (SNP) | VAF 13/66 reads (20%) | called by muse, mutect2, varscan2
